Gene-level copy-number profile of tumor specimen TCGA-CN-5361-01A from TCGA case TCGA-CN-5361, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 80.4 years (29,383 days).
Specimen TCGA-CN-5361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.28c4fe06-1e8c-48a8-a2e8-591ae7036054.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5361-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files).
https://portal.gdc.cancer.gov/files/a35e8523-2760-4565-b8f4-ec95727fe5b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 2: 15,656; copy number 3: 1,404; copy number 4: 37,407; copy number 5: 1,693; copy number 6: 985; copy number 7: 87; copy number 8: 1,898; copy number 9: 279; copy number 11: 135; copy number 12: 26; copy number 13: 13; copy number 14: 102; copy number 17: 54.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,214,510–75,240,770, 1 gene (within-gene range 0–2): AC117481.1.
- chr3:75,328,549–81,105,182, 54 genes (within-gene range 0–2): MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027.
- chr8:4,496,392–4,788,584, 3 genes: AC010941.1, AC022068.1, PAICSP4.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr9:21,802,636–22,455,740, 16 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 609 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–180,989,774, 186 genes, copy number 11–17 (within-gene range 6–17) (broad region; genes not listed).
- chr3:181,146,233–181,242,901, 3 genes, copy number 17: AC083904.1, RNU6-4P, FAUP2.
- chr3:188,947,214–189,325,304, 1 gene, copy number 13 (within-gene range 8–13): TPRG1.
- chr3:189,238,686–198,222,513, 214 genes, copy number 9–13 (broad region; genes not listed).
- chr8:37,736,601–41,032,998, 77 genes, copy number 9 (broad region; genes not listed).
- chr11:67,518,912–70,436,584, 102 genes, copy number 14 (broad region; genes not listed).
- chr19:3,296,765–3,761,692, 26 genes, copy number 12: AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
